Surgical pathology report (de-identified scan), TCGA case TCGA-HT-A5R9, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-A5R9-01A (Primary Tumor).

Tumor#

Normal#

ICD-O-3
Oligodendroglioma, anaplastic
9451/3
Site Path Brain NOS C71.9
C&C Brain, supratentorial
C71.0
JPD 2/27/13

Microscopic Description:

Sections demonstrate a variably cellular diffusely infiltrative glial neoplasm. The tumor cells consistently have rounded nuclei and perinuclear halos. In the more cellular areas in specimen 2, atypia tends to be moderate. Here, mitotic activity varies but scattered mitoses are consistently present. Up to eight mitoses are seen in 10 high power fields. There is no micro vascular proliferation. A rare microscopic focus of early tumor necrosis is seen.

Addendum Discussion:

Numerous MIB-1 reactive cells are scattered throughout the tumor. A labeling index of 14.7% is calculated, consistent with the high grade histologic features.

Addendum Diagnosis:

Anaplastic oligodendroglioma, Grade III

MIB-1 Labeling Index= 14.7%

W 2/27/13
JPD 2/27/13

Source: NCI Genomic Data Commons file c2b466d0-0e5b-46cd-9873-8d2c3c9b4623 (TCGA-HT-A5R9.D35BB9FB-030C-4B30-AE08-FFB1B39CAD6D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).